Somatic mutation profile of tumor specimen TCGA-55-8206-01A (aliquot TCGA-55-8206-01A-11D-2238-08) from TCGA case TCGA-55-8206, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 56.6 years (20,690 days).
Specimen TCGA-55-8206-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 478eb139-b068-4828-83da-baf2286cd424.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8206-10A (Blood Derived Normal), aliquot TCGA-55-8206-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0da73e8-15b2-4fa5-b3b5-6e875f2aa960

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Frame Shift Del 2, Intron 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 14/66 reads (21%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- ANK3 | c.10981C>T p.Q3661* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99781325; called by muse, mutect2, varscan2
- CACNA2D1 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV100666986; called by muse, mutect2, varscan2
- CMTR2 | c.738A>T p.E246D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100579267; called by muse, mutect2, varscan2
- CYBRD1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV100361425; called by muse, mutect2, varscan2
- DNASE2 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV99263386; called by muse, mutect2, varscan2
- FGR | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100925870; called by muse, mutect2
- GATB | c.1200C>A p.N400K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV56131421, COSV99859186; called by muse, mutect2, varscan2
- HPS1 | c.1158C>G p.S386R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.742); catalogued as COSV100282726; called by muse, varscan2
- ITGAM | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1400968587, COSV99792821; called by muse, mutect2
- KRT24 | c.272C>A p.S91Y | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52880106, COSV99232112; called by muse, mutect2, varscan2
- KRT82 | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99233782; called by muse, mutect2, varscan2
- LRP2 | c.6768T>G p.D2256E | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99789584; called by muse, mutect2, varscan2
- PRG4 | c.328C>G p.P110A | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1426969040, COSV100825875; called by muse, mutect2, varscan2
- PTPN14 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100872824; called by muse, mutect2, varscan2
- RIMS2 | c.3089C>A p.P1030Q (on ENST00000666250 / NM_001348490.2; = p.P838Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV99179367; called by muse, mutect2, varscan2
- RPS6KA1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.989); catalogued as rs775468162, COSV100837972; called by muse, mutect2, varscan2
- SLIT2 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.54); catalogued as COSV99885851; called by muse, mutect2, varscan2
- TIAM1 | c.3348G>T p.E1116D | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99737518; called by muse, mutect2, varscan2
- DOP1B | c.2310del p.E771Rfs*24 | Frame Shift Del (DEL) | VAF 29/202 reads (14%) | called by mutect2, pindel, varscan2
- SYNJ1 | c.484_520del p.N163Afs*4 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel
- ADAMTSL3 | c.1137T>C p.Y379= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV99720207; called by muse, mutect2, varscan2
- CARM1 | c.822C>T p.H274= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs764313465, COSV100499050; called by muse, mutect2, varscan2
- KIAA1191 | c.156C>T p.S52= | Silent (SNP) | VAF 34/215 reads (16%) | catalogued as rs756492730, COSV53798760; called by muse, mutect2, varscan2
- NTRK3 | c.1122C>A p.G374= | Silent (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- OTOA | c.237G>T p.R79= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV99625304; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1500C>T p.N500= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs1032434748, COSV54869277; called by muse, mutect2, varscan2
- WDR88 | c.669C>T p.S223= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs144975503; called by muse, mutect2
- TTN | c.34265-3014G>A | Intron (SNP) | VAF 14/98 reads (14%) | catalogued as COSV100599322, COSV60467074; called by muse, mutect2, varscan2
